Gene-level copy-number profile of specimen HCM-BROD-0344-C25-85A from HCMI case HCM-BROD-0344-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 73.1 years (26,701 days).
Specimen HCM-BROD-0344-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a0a9cf6e-de92-45b0-8f08-686bf25d8b1f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0344-C25-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/76a31fbd-dc73-494e-8334-2a3ad60a3e1c

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 4,897; copy number 2: 21,787; copy number 3: 24,705; copy number 4: 6,743; copy number 5: 446; copy number 6: 61; copy number 7: 1; copy number 8: 85; copy number 11: 27; copy number 12: 5; copy number 17: 60; copy number 33: 2; copy number 37: 10; copy number 38: 3; copy number 50: 5; copy number 51: 15; copy number 59: 1; copy number 61: 3; copy number 66: 2; copy number 82: 5; copy number 91: 1; copy number 97: 1; copy number 111: 2; copy number 126: 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:24,809,656–25,358,689, 6 genes: STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6, OR7K1P.
- chr21:16,525,919–18,267,373, 29 genes (within-gene range 0–1): AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3, CHODL, AF130417.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 229 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:98,877,933–100,928,540, 118 genes, copy number 7–12 (broad region; genes not listed).
- chr8:7,414,855–8,049,267, 48 genes, copy number 17: DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1, FAM90A6P, FAM90A7P, FAM90A21P, FAM90A22P, FAM90A23P, OR7E157P, AC134684.1, AC084121.1, OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:8,086,022–8,116,949, 4 genes, copy number 17: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:11,676,959–11,763,223, 2 genes, copy number 111: GATA4, C8orf49.
- chr8:11,842,524–11,933,203, 4 genes, copy number 82: CTSB, AC025857.1, OR7E158P, OR7E161P.
- chr8:12,043,506–12,665,588, 33 genes, copy number 17–51 (within-gene range 1–51): DEFB131C, DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P, ALG1L11P, FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2.
- chr8:17,156,482–17,302,427, 3 genes, copy number 61 (within-gene range 1–61): ZDHHC2, CNOT7, VPS37A.
- chr14:37,556,158–37,596,059, 3 genes, copy number 91–126 (within-gene range 2–126): AL121790.2, AL121790.1, FOXA1.
- chr17:65,538,102–66,192,133, 4 genes, copy number 38–59 (within-gene range 3–59): AC004805.1, CEP112, AC004805.3, AC004805.2.
- chr17:67,717,931–67,984,378, 5 genes, copy number 50 (within-gene range 3–50): NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF.
- chr22:24,806,169–24,946,695, 3 genes, copy number 66–82: SGSM1, AL049759.1, TMEM211.
- chr22:26,161,834–26,169,341, 2 genes, copy number 33: LINC02559, AL022337.1.

Autosomal genes at a single copy (total copy number 1): 2,041. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
